Somatic mutation profile of tumor specimen TCGA-P8-A6RX-01A (aliquot TCGA-P8-A6RX-01A-11D-A35D-08) from TCGA case TCGA-P8-A6RX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 65.2 years (23,825 days).
Specimen TCGA-P8-A6RX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cabc1f50-5fb2-45f3-90bc-bc6c72a374af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P8-A6RX-10A (Blood Derived Normal), aliquot TCGA-P8-A6RX-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46a207fd-6fc4-4696-9b46-67fdb189945a

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Nonsense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4414C>T p.R1472C (on ENST00000272895 / NM_173076.3; = p.R1154C on NM_015657.3) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs755379562; called by muse, mutect2, varscan2
- APBA1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.04); catalogued as rs777572294; called by muse, mutect2, varscan2
- BMP1 | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs1408532122; called by muse, mutect2, varscan2
- CD5L | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145458344, COSV63821515; called by muse, mutect2, varscan2
- CNTN1 | c.1377C>A p.S459R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1366362249; called by muse, mutect2, varscan2
- ENC1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs61758147, COSV56629644; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs530958757; called by muse, mutect2, varscan2
- PSAT1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs759482379; called by muse, mutect2, varscan2
- SDC2 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs183417451; called by muse, mutect2, varscan2
- SPATA31D1 | c.2620C>T p.R874* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs1346441428, COSV61194412; called by muse, mutect2, varscan2
- TEX14 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs754550862; called by muse, mutect2, varscan2
- USP15 | c.2128C>T p.R710* (on ENST00000280377 / NM_001351159.2; = p.R681* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV99738527; called by muse, mutect2, varscan2
- KDM6B | c.2575G>A p.G859S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MYOM3 | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- OGT | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2384A>T p.H795L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TPX2 | c.1035G>T p.R345S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TSHZ1 | c.1599C>G p.Y533* (on ENST00000580243 / NM_001308210.2; = p.Y488* on NM_005786.6) | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- IGHA2 | c.513C>T p.S171= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs782813367; called by muse, mutect2, varscan2
- PRB2 | c.597A>G p.G199= | Silent (SNP) | VAF 72/291 reads (25%) | called by muse, varscan2
